Somatic mutation profile of tumor specimen TCGA-BB-A5HY-01A (aliquot TCGA-BB-A5HY-01A-11D-A28R-08) from TCGA case TCGA-BB-A5HY, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 64.7 years (23,640 days).
Specimen TCGA-BB-A5HY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1516541-831d-4978-bf29-aa82c13c112d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-A5HY-10A (Blood Derived Normal), aliquot TCGA-BB-A5HY-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a52e257-86e7-4a49-94f8-54f4c0a92147

The open-access MAF lists 223 somatic variants for this specimen: 175 protein-altering or splice-affecting, 41 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 41, Nonsense Mutation 8, Frame Shift Del 6, Intron 5, Splice Region 4, Frame Shift Ins 4, In Frame Del 2, 3'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1579C>T p.R527C (on ENST00000399959; = p.R528C on NM_001356.5) | Missense Mutation (SNP) | VAF 76/113 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1064795323, COSV67863221; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.818C>T p.S273L (on ENST00000326195 / NM_001025091.2; = p.S235L on NM_001090.3) | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV100400779; called by muse, mutect2, varscan2
- AGAP2 | c.2692C>T p.R898W (on ENST00000547588 / NM_001122772.2; = p.R542W on NM_014770.4) | Missense Mutation (SNP) | VAF 151/272 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV57729438; called by muse, mutect2, varscan2
- AKAP9 | c.11431C>T p.R3811* (on ENST00000359028; = p.R3787* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as rs183257184, COSV62342914; called by muse, mutect2, varscan2
- ALKBH5 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as COSV52760102; called by muse, mutect2, varscan2
- ANK3 | c.5971G>C p.E1991Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.477); catalogued as COSV99779226; called by muse, mutect2, varscan2
- ANKRD30A | c.886G>A p.E296K (on ENST00000611781; = p.E240K on NM_052997.2) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV100653216; called by muse, mutect2, varscan2
- AP3D1 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs1348418580, COSV61433368; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1436G>T p.R479I | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100771860; called by muse, mutect2, varscan2
- ARNT2 | c.1732C>G p.R578G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100308811; called by muse, mutect2, varscan2
- ASPM | c.1711G>C p.V571L | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99660005; called by muse, mutect2, varscan2
- ATP2A3 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752171448, COSV99988991; called by muse, mutect2, varscan2
- BRD4 | c.3314A>G p.Q1105R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.775); catalogued as COSV99650243; called by muse, mutect2, varscan2
- BTG3 | c.314A>T p.Y105F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100336270; called by muse, mutect2, varscan2
- CACNG3 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.497); catalogued as COSV99135751; called by muse, mutect2, varscan2
- CACNG5 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs563780871, COSV50055316, COSV99400473; called by muse, mutect2, varscan2
- CASP6 | c.839C>G p.S280* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV99488633; called by muse, mutect2, varscan2
- CDH1 | c.2059G>C p.D687H | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV99931090, COSV99931619; called by muse, mutect2, varscan2
- CDK8 | c.703C>A p.H235N | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV101037077; called by muse, mutect2, varscan2
- CFAP44 | c.252A>C p.T84= | Splice Region (SNP) | VAF 16/97 reads (16%) | catalogued as COSV99869260; called by muse, mutect2, varscan2
- CLEC17A | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100355182; called by muse, mutect2, varscan2
- CNOT1 | c.2968G>C p.E990Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV99799769; called by muse, mutect2, varscan2
- COL11A2 | c.4018G>T p.D1340Y (on ENST00000341947 / NM_080680.3; = p.D1233Y on NM_080679.2) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100553704; called by muse, mutect2, varscan2
- COL4A3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as rs752030126, COSV101170162; called by muse, mutect2, varscan2
- COL6A3 | c.5200G>C p.E1734Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as COSV55095039, COSV99797203; called by muse, mutect2, varscan2
- CRLF3 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV100158349; called by muse, mutect2, varscan2
- CYB5R3 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs777817919, COSV100677837; called by muse, mutect2, varscan2
- DDX5 | c.810A>G p.R270= | Splice Region (SNP) | VAF 87/171 reads (51%) | catalogued as rs1218638314, COSV99857806; called by muse, mutect2, varscan2
- DDX59 | c.1829G>T p.R610I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as rs748521357, COSV100494484, COSV100494694, COSV58753759; called by muse, mutect2, varscan2
- DENND4C | c.2589G>A p.K863= | Splice Region (SNP) | VAF 5/15 reads (33%) | catalogued as rs1372064579, COSV100991248; called by muse, varscan2
- DNAJC2 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99971701; called by muse, mutect2, varscan2
- DNMT3B | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52424605, COSV99140820; called by muse, mutect2, varscan2
- DOCK10 | c.3814G>T p.A1272S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV99288670; called by muse, mutect2, varscan2
- DOCK6 | c.4433G>A p.R1478H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs776844030, COSV99625192; called by muse, mutect2, varscan2
- DST | c.3820G>A p.V1274I (on ENST00000361203 / NM_001374722.1; = p.V948I on NM_001723.6) | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1181400642, COSV99753748; called by muse, mutect2, varscan2
- DYNC2I1 | c.2620A>G p.N874D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.33); catalogued as COSV101337642; called by muse, mutect2, varscan2
- EGFR | c.1255G>C p.A419P | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV99289265; called by muse, mutect2
- EIF4B | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV100016727; called by muse, mutect2, varscan2
- ELOVL7 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs866433834, COSV101415555; called by muse, mutect2, varscan2
- EPHB4 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as COSV100639457; called by muse, mutect2, varscan2
- ERBB4 | c.3703A>G p.K1235E | Missense Mutation (SNP) | VAF 66/114 reads (58%) | SIFT tolerated (0.84); PolyPhen benign (0.073); catalogued as COSV100724705; called by muse, mutect2, varscan2
- ESR1 | c.1110G>T p.L370F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52803226, COSV52804355; called by muse, mutect2, varscan2
- FAM118B | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV100796858; called by muse, mutect2, varscan2
- FAM166A | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100457811; called by muse, mutect2
- FAM174B | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100526536; called by muse, mutect2, varscan2
- FAM71B | c.682T>A p.S228T | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs761826559, COSV100261979; called by muse, mutect2, varscan2
- FAT2 | c.5651C>A p.P1884H | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99942254; called by muse, mutect2, varscan2
- FAT4 | c.6439A>G p.I2147V | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757978155, COSV100628019; called by muse, mutect2, varscan2
- FKBP8 | c.823C>G p.L275V (on ENST00000222308 / NM_001308373.2; = p.L276V on NM_012181.5) | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as COSV99723988; called by muse, mutect2, varscan2
- FLII | c.1001A>G p.E334G | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100493559; called by muse, mutect2, varscan2
- FLRT3 | c.1778C>G p.S593C | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as rs1427635276, COSV99429490; called by muse, mutect2, varscan2
- FMO3 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as rs1351220508, COSV100882418; called by muse, mutect2
- FREM1 | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101084134; called by muse, mutect2, varscan2
- GALNT17 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs267601554, COSV100351772, COSV61165138; called by muse, mutect2, varscan2
- GGTLC1 | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99600541; called by muse, mutect2, varscan2
- GLI3 | c.4231G>A p.D1411N | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.576); catalogued as COSV101229794; called by muse, mutect2, varscan2
- GLYAT | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99557230, COSV99557507; called by muse, mutect2, varscan2
- GOLGB1 | c.4631_4633del p.L1544del | In Frame Del (DEL) | VAF 22/135 reads (16%) | catalogued as rs1217997729; called by pindel, varscan2
- GPR150 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.53); PolyPhen benign (0.14); catalogued as rs747807886, COSV101187400; called by muse, mutect2, varscan2
- GSTP1 | c.211C>G p.R71G | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV101282016, COSV66992352; called by muse, mutect2, varscan2
- GTF3C5 | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100565348; called by mutect2, varscan2
- HELZ2 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64410574; called by muse, mutect2
- HEPH | c.1294C>T p.R432* (on ENST00000343002; = p.R165* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV57961523, COSV57962751; called by muse, mutect2
- HHIPL2 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV100597035, COSV58565597; called by muse, mutect2, varscan2
- IFT46 | c.911G>C p.S304T (on ENST00000264021 / NM_001168618.2; = p.S355T on NM_020153.3) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV99870958; called by muse, mutect2, varscan2
- IL17RB | c.1330G>A p.V444M | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs771966837, COSV99213644; called by muse, mutect2, varscan2
- INCA1 | c.454G>A p.E152K (on ENST00000574617 / NM_001167986.1; = p.E137K on NM_213726.2) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1221440407, COSV100742016; called by muse, mutect2, varscan2
- INTS9 | c.7C>T p.L3= | Splice Region (SNP) | VAF 12/21 reads (57%) | catalogued as COSV99816016; called by muse, mutect2, varscan2
- INVS | c.2713A>T p.R905* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV99317333; called by muse, mutect2, varscan2
- IRAK3 | c.667A>T p.N223Y | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99706060; called by muse, mutect2, varscan2
- ITGA4 | c.1729A>G p.I577V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99276033; called by muse, mutect2, varscan2
- KCNJ2 | c.83A>G p.N28S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.588); catalogued as COSV99696306; called by muse, mutect2, varscan2
- KIF4B | c.2374C>G p.P792A | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV101469226; called by muse, mutect2, varscan2
- KIF7 | c.2876A>T p.K959M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99176169; called by muse, mutect2, varscan2
- KRTAP11-1 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60095635; called by muse, mutect2
- LAMA3 | c.4412G>A p.R1471Q | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1005920516, COSV100556180; called by muse, mutect2, varscan2
- LCN12 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100861310; called by muse, mutect2
- LMLN | c.554G>T p.C185F | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100218453; called by muse, mutect2, varscan2
- LRP1 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as rs768155333, COSV54526100; called by muse, mutect2, varscan2
- MAGI2 | c.3688G>A p.G1230R | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833899; called by muse, mutect2, varscan2
- MAN1A1 | c.1582G>A p.G528S | Missense Mutation (SNP) | VAF 79/118 reads (67%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.867); catalogued as COSV100870609; called by muse, mutect2, varscan2
- MAST1 | c.3140T>A p.V1047E | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99262638; called by muse, mutect2, varscan2
- MFAP3 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100491557; called by muse, mutect2, varscan2
- MFSD8 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.744); catalogued as COSV99614287; called by muse, mutect2, varscan2
- MKI67 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV100896374; called by muse, mutect2, varscan2
- MLXIP | c.1654A>C p.K552Q | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV100038591; called by muse, mutect2, varscan2
- MME | c.1654C>G p.Q552E | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV100852340; called by muse, mutect2, varscan2
- MR1 | c.815G>C p.S272T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV99294837; called by muse, mutect2, varscan2
- MST1 | c.995C>G p.T332R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs1317112946, COSV99610672; called by muse, mutect2, varscan2
- MYOF | c.4840C>G p.Q1614E | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV100825521; called by muse, mutect2, varscan2
- MYOZ3 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51739785; called by muse, mutect2, varscan2
- NCOA3 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs145292442; called by muse, mutect2, varscan2
- NEU4 | c.1186C>G p.L396V (on ENST00000391969 / NM_001167602.3; = p.L408V on NM_080741.4) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100371927, COSV57991695; called by muse, mutect2, varscan2
- NFATC2 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65353182; called by muse, mutect2
- NLRP11 | c.1795C>G p.Q599E | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100789691; called by muse, mutect2, varscan2
- NPAP1 | c.1499C>G p.P500R | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100275052, COSV61506453; called by muse, mutect2, varscan2
- NPHP3 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1214358241, COSV100446731; called by muse, mutect2, varscan2
- OPHN1 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100830333; called by muse, mutect2, varscan2
- OR52E8 | c.195G>T p.M65I | Missense Mutation (SNP) | VAF 88/140 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV101190123; called by muse, mutect2, varscan2
- OR6F1 | c.808C>A p.L270M | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.974); catalogued as COSV57468267; called by muse, mutect2, varscan2
- PACS1 | c.2425G>A p.V809M | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs369934909; called by muse, mutect2, varscan2
- PAPPA2 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs746410678, COSV62775917; called by muse, mutect2, varscan2
- PCDH15 | c.3028G>C p.D1010H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100218229; called by muse, mutect2, varscan2
- PDZRN3 | c.1518+1G>T p.X506_splice | Splice Site (SNP) | VAF 104/195 reads (53%) | catalogued as rs866699967, COSV99728706; called by muse, mutect2, varscan2
- PGK2 | c.477C>A p.D159E | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100505402; called by muse, mutect2, varscan2
- PIAS1 | c.1767T>G p.F589L | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99986678; called by muse, mutect2, varscan2
- PIK3R4 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100768332; called by muse, mutect2, varscan2
- PLAAT2 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 82/169 reads (49%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.492); catalogued as COSV99738102; called by muse, mutect2, varscan2
- PNPLA1 | c.892C>G p.R298G (on ENST00000394571 / NM_001374623.1; = p.R203G on NM_173676.2) | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100462899; called by muse, mutect2, varscan2
- POLR2B | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV100107968; called by muse, mutect2, varscan2
- POU3F3 | c.287A>C p.Q96P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV100796848; called by muse, mutect2, varscan2
- PPP1R9A | c.351G>C p.E117D | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.318); catalogued as COSV99195104; called by muse, mutect2, varscan2
- PSIP1 | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 78/116 reads (67%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs1001300282, COSV101050918; called by muse, mutect2, varscan2
- PTPN21 | c.679A>C p.S227R | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100161740; called by muse, varscan2
- PUM2 | c.1139C>G p.P380R | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.087); catalogued as COSV100163408; called by muse, mutect2, varscan2
- RACGAP1 | c.1582G>A p.V528I | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV100407651; called by muse, mutect2, varscan2
- REEP6 | c.517G>C p.V173L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as COSV52015028, COSV99278525; called by muse, mutect2, varscan2
- RET | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV100393053; called by muse, mutect2, varscan2
- RIMS2 | c.1850G>T p.C617F (on ENST00000666250 / NM_001348490.2; = p.C425F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51720955, COSV99165608; called by muse, mutect2, varscan2
- RNF6 | c.970C>G p.H324D | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV100644611; called by muse, mutect2, varscan2
- ROS1 | c.5542A>C p.I1848L | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs765553432, COSV100876820; called by muse, mutect2, varscan2
- RPGRIP1 | c.2901G>C p.Q967H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.72); catalogued as COSV99250747; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100402462; called by muse, mutect2, varscan2
- RSRC1 | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 32/107 reads (30%) | catalogued as COSV55828915; called by muse, mutect2, varscan2
- RYR2 | c.8623G>C p.D2875H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100769153; called by muse, mutect2, varscan2
- SETD1A | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 76/122 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs1421590782, COSV99352714; called by muse, mutect2, varscan2
- SHC3 | c.1467G>C p.K489N | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV101011843, COSV101011911; called by muse, mutect2, varscan2
- SLC8B1 | c.1699T>G p.F567V | Missense Mutation (SNP) | VAF 75/116 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99176676; called by muse, mutect2, varscan2
- SNTG2 | c.721T>A p.W241R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs760878590, COSV100421980; called by muse, mutect2, varscan2
- SORCS1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs1238754962, COSV53848358, COSV53865482; called by muse, mutect2, varscan2
- SP100 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.168); catalogued as COSV99892775; called by muse, mutect2, varscan2
- SPEN | c.3357A>T p.L1119F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV101005098; called by muse, mutect2, varscan2
- SRP54 | c.1042A>C p.I348L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV99392481; called by muse, mutect2
- STX7 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV100908421; called by muse, mutect2
- SUPT6H | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV100112248; called by muse, mutect2, varscan2
- TMEM185A | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 215/423 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100382975; called by muse, mutect2, varscan2
- TMEM67 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs369219859; called by muse, mutect2, varscan2
- TPCN2 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); catalogued as rs575128798, COSV53732027; called by muse, mutect2, varscan2
- TRHDE | c.2916A>T p.E972D | Missense Mutation (SNP) | VAF 83/114 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.193); catalogued as COSV99670026; called by muse, mutect2, varscan2
- TRIM26 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.301); catalogued as rs144770536; called by muse, mutect2, varscan2
- TRIO | c.5111C>G p.S1704C | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV100710149; called by muse, mutect2, varscan2
- TRRAP | c.9941T>C p.L3314P (on ENST00000359863 / NM_001244580.1; = p.L3285P on NM_003496.3) | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100722280; called by muse, mutect2, varscan2
- TSPYL2 | c.1101G>A p.W367* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100212161; called by muse, mutect2, varscan2
- TTN | c.100823C>T p.S33608F (on ENST00000591111; = p.S26184F on NM_003319.4) | Missense Mutation (SNP) | VAF 110/136 reads (81%) | PolyPhen possibly damaging (0.679); catalogued as COSV100603251, COSV59893612; called by muse, mutect2, varscan2
- TTN | c.84793G>T p.D28265Y (on ENST00000591111; = p.D20841Y on NM_003319.4) | Missense Mutation (SNP) | VAF 26/129 reads (20%) | PolyPhen probably damaging (0.999); catalogued as COSV100603252; called by muse, mutect2, varscan2
- UGGT2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV65026118; called by muse, mutect2, varscan2
- UGT2B7 | c.479T>A p.L160Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100535149; called by muse, mutect2, varscan2
- UHRF1BP1L | c.534G>C p.L178F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54439768, COSV99691330; called by muse, mutect2, varscan2
- USP9X | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV61073176; called by muse, mutect2, varscan2
- WDFY3 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99882856; called by muse, mutect2, varscan2
- XRCC5 | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV101079429, COSV101079474; called by muse, mutect2, varscan2
- XRN2 | c.1440C>A p.F480L | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101018184; called by muse, mutect2, varscan2
- ZDHHC12 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV52574661; called by muse, mutect2, varscan2
- ZDHHC17 | c.1457T>A p.L486Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100602055; called by muse, mutect2, varscan2
- ZNF248 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as COSV100627523; called by muse, mutect2, varscan2
- ZNF264 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as COSV99567182; called by muse, mutect2, varscan2
- ZNF516 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | catalogued as COSV71587358; called by muse, mutect2
- ZNF518A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV100283447; called by muse, mutect2, varscan2
- ZNF665 | c.212A>G p.H71R (on ENST00000600412; = p.H136R on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/91 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs374207298; called by muse, mutect2, varscan2
- ZNF80 | c.689A>C p.Y230S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100351983; called by muse, mutect2, varscan2
- ZNF81 | c.886C>T p.H296Y | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.896); catalogued as rs782555368, COSV58575073; called by muse, mutect2, varscan2
- ZP3 | c.397C>T p.R133C (on ENST00000394857 / NM_001110354.2; = p.R82C on NM_007155.6) | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs149364780; called by muse, mutect2, varscan2
- ZRANB1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100669109; called by muse, mutect2, varscan2
- AJUBA | c.688dup p.S230Ffs*76 | Frame Shift Ins (INS) | VAF 10/12 reads (83%) | called by mutect2, varscan2
- ATAD5 | c.3176_3179dup p.Q1061Tfs*6 | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- BRINP1 | c.1717del p.E573Rfs*90 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | called by mutect2, pindel, varscan2
- CCDC87 | c.624_628del p.I209Lfs*14 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- CDKN2A | c.128_131dup p.Y44* | Nonsense Mutation (INS) | VAF 84/169 reads (50%) | called by mutect2, pindel, varscan2
- PFKM | c.264del p.C89Afs*18 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- ROBO1 | c.1033del p.L345* | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- SLC22A23 | c.1253dup p.V419Rfs*50 | Frame Shift Ins (INS) | VAF 31/62 reads (50%) | called by mutect2, pindel, varscan2
- TCHP | c.1134+1dup | Frame Shift Ins (INS) | VAF 39/68 reads (57%) | called by mutect2, pindel, varscan2
- TP53 | c.551_554del p.D184Afs*62 | Frame Shift Del (DEL) | VAF 43/68 reads (63%) | called by mutect2, pindel, varscan2
- TTC39B | c.195_203delinsCTGGAA p.R65_A68delinsSWK | In Frame Del (DEL) | VAF 11/20 reads (55%) | called by pindel, varscan2*
- ZNF440 | c.644_645del p.Y215Sfs*4 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by pindel, varscan2
- ADCY1 | c.570G>A p.V190= | Silent (SNP) | VAF 44/59 reads (75%) | catalogued as COSV99811691; called by muse, mutect2, varscan2
- ADCY2 | c.1053C>G p.L351= | Silent (SNP) | VAF 67/122 reads (55%) | catalogued as COSV100602387; called by muse, mutect2, varscan2
- AHDC1 | c.456G>A p.L152= | Silent (SNP) | VAF 57/194 reads (29%) | catalogued as COSV99899111; called by muse, mutect2, varscan2
- ANKS3 | c.252C>T p.I84= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs779238364, COSV58508337; called by muse, mutect2, varscan2
- ANXA2R | c.105G>T p.P35= | Silent (SNP) | VAF 112/240 reads (47%) | catalogued as COSV100148636; called by muse, mutect2, varscan2
- C1QTNF9 | c.69C>T p.C23= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs767057381, COSV100129847; called by muse, mutect2, varscan2
- CCDC185 | c.600C>T p.F200= | Silent (SNP) | VAF 77/168 reads (46%) | catalogued as rs761008873, COSV100838778; called by muse, mutect2, varscan2
- COL3A1 | c.4311G>A p.V1437= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV58584238, COSV58585790; called by muse, mutect2, varscan2
- DDX51 | c.1662G>A p.G554= | Silent (SNP) | VAF 75/122 reads (61%) | catalogued as rs1241912775, COSV100223005; called by muse, mutect2, varscan2
- DMD | c.6151C>A p.R2051= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100818956, COSV63777537; called by muse, mutect2
- DOCK5 | c.1407G>T p.T469= | Silent (SNP) | VAF 108/199 reads (54%) | catalogued as COSV99376534; called by muse, mutect2, varscan2
- DSEL | c.891C>T p.V297= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100025468; called by muse, mutect2, varscan2
- GAS6 | c.285C>T p.C95= | Silent (SNP) | VAF 72/103 reads (70%) | catalogued as COSV100581318; called by muse, mutect2, varscan2
- KMT2C | c.14580G>A p.V4860= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV100069817; called by muse, mutect2, varscan2
- LHX1 | c.723G>A p.L241= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- LRP1B | c.4260C>T p.D1420= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV101254857; called by muse, mutect2, varscan2
- MAK | c.193T>C p.L65= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs750895183, COSV100504344; called by muse, mutect2, varscan2
- MTAP | c.573G>A p.A191= | Silent (SNP) | VAF 58/93 reads (62%) | catalogued as rs372861176; called by muse, mutect2, varscan2
- NCAM2 | c.183A>T p.I61= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99522380; called by muse, mutect2, varscan2
- NRCAM | c.2454G>A p.L818= (on ENST00000379028 / NM_001371124.1; = p.L802= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs1391088836, COSV100694523; called by muse, mutect2, varscan2
- OR4F5 | c.471G>A p.V157= | Silent (SNP) | VAF 139/184 reads (76%) | catalogued as COSV100633174; called by muse, mutect2, varscan2
- PAQR5 | c.486C>T p.L162= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100575433; called by muse, mutect2, varscan2
- PARM1 | c.444C>T p.L148= | Silent (SNP) | VAF 73/239 reads (31%) | catalogued as rs374029387, COSV100267941; called by muse, mutect2, varscan2
- PAWR | c.636C>G p.S212= | Silent (SNP) | VAF 60/205 reads (29%) | catalogued as COSV100174172; called by muse, mutect2, varscan2
- PCDHB5 | c.300A>G p.E100= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV99167725; called by muse, mutect2, varscan2
- PITPNM1 | c.2238G>A p.P746= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs774692847, COSV62707861; called by muse, mutect2, varscan2
- PRAMEF2 | c.105C>G p.L35= | Silent (SNP) | VAF 85/142 reads (60%) | catalogued as rs1437661761, COSV99535055; called by muse, mutect2, varscan2
- PRR23B | c.336A>G p.S112= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as COSV100272007; called by muse, mutect2, varscan2
- RBBP8NL | c.1395C>G p.L465= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99436449; called by muse, mutect2, varscan2
- RBM39 | c.1425T>C p.Y475= (on ENST00000253363 / NM_001323424.2; = p.Y469= on NM_004902.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as rs1387971109, COSV99488399; called by muse, mutect2, varscan2
- RPH3A | c.1716A>T p.I572= (on ENST00000389385 / NM_001143854.2; = p.I568= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV101231794; called by muse, mutect2
- SHOX2 | c.945C>T p.I315= (on ENST00000441443 / NM_006884.3; = p.I339= on NM_003030.4) | Silent (SNP) | VAF 230/888 reads (26%) | catalogued as COSV101273762, COSV101273775; called by muse, varscan2
- SIGIRR | c.591C>A p.L197= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100229901; called by muse, mutect2, varscan2
- SLC51A | c.516C>T p.L172= | Silent (SNP) | VAF 28/247 reads (11%) | catalogued as COSV99580133; called by muse, varscan2
- SYNJ2 | c.462T>G p.S154= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV100840112; called by muse, mutect2, varscan2
- TBC1D22B | c.294C>T p.A98= | Silent (SNP) | VAF 48/142 reads (34%) | catalogued as COSV100996742; called by muse, mutect2, varscan2
- TRIM71 | c.2427T>C p.I809= | Silent (SNP) | VAF 95/149 reads (64%) | catalogued as COSV101070402; called by muse, mutect2, varscan2
- TUT4 | c.4344T>G p.S1448= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as COSV99932051; called by muse, mutect2, varscan2
- UBA7 | c.3022C>T p.L1008= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs1128278, COSV100323569; called by muse, mutect2, varscan2
- WDR46 | c.1779G>A p.A593= | Silent (SNP) | VAF 99/237 reads (42%) | catalogued as rs2475, COSV101005597; called by muse, mutect2, varscan2
- XIRP2 | c.5037G>A p.Q1679= (on ENST00000628543; = p.Q1854= on NM_152381.6) | Silent (SNP) | VAF 64/92 reads (70%) | catalogued as COSV54682900; called by muse, mutect2, varscan2
- CPLANE1 | c.*4801G>C | 3'UTR (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99950124; called by muse, mutect2, varscan2
- CSH1 | c.457-46C>G | Intron (SNP) | VAF 46/162 reads (28%) | catalogued as rs746849327, COSV100298278; called by muse, mutect2, varscan2
- MPIG6B | c.621+27T>G | Intron (SNP) | VAF 23/110 reads (21%) | catalogued as COSV101008065; called by muse, mutect2, varscan2
- TTN | c.34264+5520C>T | Intron (SNP) | VAF 68/81 reads (84%) | catalogued as rs761169549, COSV100595360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VNN3 | c.*295T>A | 3'UTR (SNP) | VAF 38/48 reads (79%) | catalogued as COSV99258172; called by muse, mutect2, varscan2
- ZNF544 | c.244+4569C>T | Intron (SNP) | VAF 17/83 reads (20%) | catalogued as rs1568482033, COSV99516925, COSV99517207; called by muse, mutect2, varscan2
- ZNF548 | c.16-2849G>A | Intron (SNP) | VAF 7/22 reads (32%) | catalogued as rs763643625, COSV100278060; called by muse, mutect2, varscan2
